Somatic mutation profile of tumor specimen MP2PRT-PASMVF-TMP1-A (aliquot MP2PRT-PASMVF-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PASMVF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.2 years (1,163 days).
Specimen MP2PRT-PASMVF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec0c0ace-49cd-48e2-9530-19a62bef4b65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMVF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMVF-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53a758b4-49c3-4da8-936b-ebc3ba313481

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 84/257 reads (33%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGTR1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs56257794, COSV62557506; called by muse, mutect2, varscan2
- C1GALT1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99777604; called by muse, mutect2
- FSIP2 | c.11635G>C p.E3879Q | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58080369; called by muse, mutect2, varscan2
- GRIA3 | c.754T>C p.F252L | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV52055661; called by muse, mutect2
- KRT16 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 105/589 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as rs767053955; called by muse, mutect2, varscan2
- PDE3A | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62970102; called by muse, mutect2, varscan2
- STKLD1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.556); catalogued as rs587672490, COSV64315058; called by muse, mutect2
- TJP3 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs774395822; called by muse, mutect2
- ATP8A2 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- BBX | c.1282_1283insTGGCCCCT p.H428Lfs*12 | Frame Shift Ins (INS) | VAF 36/313 reads (12%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3133G>A p.E1045K (on ENST00000297405 / NM_001363185.1; = p.E941K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.685); called by muse, mutect2
- MAGI2 | c.3123G>C p.Q1041H | Missense Mutation (SNP) | VAF 38/825 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); called by muse, mutect2
- PLK4 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2
- TOPAZ1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- AGXT | c.816G>A p.L272= | Silent (SNP) | VAF 26/616 reads (4%) | called by muse, mutect2
- CROCC2 | c.3972C>T p.S1324= | Silent (SNP) | VAF 17/535 reads (3%) | called by muse, mutect2
- F9 | c.1344C>T p.S448= | Silent (SNP) | VAF 16/542 reads (3%) | catalogued as CX900305, COSV99496416; called by muse, mutect2
- ITGB6 | c.1776C>T p.S592= | Silent (SNP) | VAF 83/461 reads (18%) | catalogued as rs751270189, COSV99325206; called by muse, mutect2, varscan2
- KCNV2 | c.972G>A p.T324= | Silent (SNP) | VAF 17/554 reads (3%) | catalogued as rs1443842786; called by muse, mutect2
- RGL2 | c.1956C>T p.I652= | Silent (SNP) | VAF 170/624 reads (27%) | called by muse, mutect2, varscan2
- TMEM275 | c.159C>T p.A53= | Silent (SNP) | VAF 63/964 reads (7%) | called by muse, mutect2
